Somatic mutation profile of tumor specimen TCGA-FD-A5BU-01A (aliquot TCGA-FD-A5BU-01A-31D-A26M-08) from TCGA case TCGA-FD-A5BU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 76.3 years (27,882 days).
Specimen TCGA-FD-A5BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca48f9e-17b2-43a4-992e-ed3488ff55d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BU-10A (Blood Derived Normal), aliquot TCGA-FD-A5BU-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1161c30f-537e-4f2d-9ec2-95ea7b88859d

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 12, Frame Shift Ins 4, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960012, COSV67960020, COSV67960088; called by muse, mutect2, varscan2
- ADAR | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as CD138550, COSV52722285; called by muse, mutect2, varscan2
- ADGRG4 | c.7409A>G p.D2470G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99797278; called by muse, mutect2
- AFF2 | c.3002T>C p.I1001T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54010490; called by muse, mutect2, varscan2
- AL031777.2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61912500; called by muse, mutect2, varscan2
- C12orf40 | c.1616G>C p.R539T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV104410247, COSV61134900, COSV61138477; called by muse, mutect2, varscan2
- CADM1 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV59025016; called by muse, mutect2, varscan2
- CBLN2 | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54053378; called by muse, mutect2, varscan2
- CD248 | c.1432C>G p.R478G | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs770613673, COSV60938113; called by muse, mutect2, varscan2
- CEP128 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99383813; called by muse, mutect2, varscan2
- CHAF1A | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs770908974, COSV56677012; called by muse, mutect2, varscan2
- CUBN | c.6728C>T p.P2243L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs544059289, COSV64715627, COSV64727491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDN | c.1363A>G p.I455V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV60295074; called by muse, mutect2, varscan2
- DOCK8 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759788300, COSV66635635; called by muse, mutect2, varscan2
- F8 | c.6567T>A p.D2189E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57706863; called by muse, mutect2, varscan2
- GALR1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as COSV55319514; called by muse, mutect2, varscan2
- GIMAP1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs1448707179, COSV56190124; called by muse, mutect2, varscan2
- ITGBL1 | c.384C>A p.Y128* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV101095900; called by muse, mutect2, varscan2
- KCNJ1 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60663204; called by muse, mutect2, varscan2
- KIAA1109 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370494942, COSV52689577; called by muse, mutect2, varscan2
- LIG1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs574879811, COSV54393430; called by muse, mutect2, varscan2
- LRRC18 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765969044, COSV53284317, COSV53286318; called by muse, mutect2, varscan2
- MAP7D3 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60172947; called by muse, mutect2, varscan2
- MAST2 | c.4913C>A p.T1638N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs377756048; called by muse, mutect2, varscan2
- MYBL2 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53834356; called by muse, mutect2, varscan2
- MYH8 | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67971433; called by muse, mutect2
- MYO15A | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV52768022; called by mutect2, varscan2
- MYOC | c.950T>C p.I317T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV50680584; called by muse, mutect2, varscan2
- NRK | c.1162del p.E388Nfs*42 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs1328508612, COSV99688736; called by mutect2, pindel, varscan2
- OR5AP2 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.604); catalogued as COSV100266241, COSV57258336, COSV57259304; called by muse, mutect2, varscan2
- OSBPL8 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53890160; called by muse, mutect2, varscan2
- PCDHGA10 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.432); catalogued as rs1359274012, COSV54050061; called by muse, mutect2, varscan2
- PDCD7 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52601645; called by muse, mutect2, varscan2
- PLA2G4C | c.1590C>A p.Y530* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99506766; called by muse, mutect2, varscan2
- PTGFRN | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV67799791; called by muse, mutect2, varscan2
- PTPN21 | c.2451G>T p.R817S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60852624; called by muse, mutect2, varscan2
- RRP8 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV54450954; called by muse, mutect2, varscan2
- SATB2 | c.1926G>T p.Q642H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53493771; called by muse, mutect2, varscan2
- SEMA6D | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs534298453, COSV60379557; called by muse, mutect2, varscan2
- SLC5A8 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV73311288; called by muse, mutect2, varscan2
- SP140 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1032805500, COSV59455335, COSV59455928; called by muse, mutect2, varscan2
- ST18 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760075725, COSV52495567; called by muse, mutect2, varscan2
- TSC1 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53774382; called by muse, mutect2, varscan2
- UBR4 | c.11648G>A p.C3883Y | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV64401837; called by muse, mutect2, varscan2
- UPF1 | c.3088G>A p.G1030R (on ENST00000599848 / NM_001297549.2; = p.G1019R on NM_002911.4) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53202806; called by muse, mutect2, varscan2
- XXYLT1 | c.418C>G p.H140D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58756744; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZNF786 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs765306158, COSV60276701, COSV60277304; called by muse, mutect2, varscan2
- FOSL2 | c.616dup p.L206Pfs*53 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- HES1 | c.708_709dup p.A237Gfs*80 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- KMT2D | c.1829dup p.P611Sfs*3 | Frame Shift Ins (INS) | VAF 8/75 reads (11%) | called by pindel, varscan2
- KRTAP12-1 | c.151del p.Q51Sfs*8 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- NDUFV2 | c.662dup p.R222Tfs*5 | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- ADA | c.642C>T p.H214= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs562055008, COSV63068907; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CRYBG2 | c.1170T>A p.P390= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV57486274; called by muse, mutect2
- DNAH5 | c.6222C>T p.N2074= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54257176; called by muse, mutect2, varscan2
- KMT2D | c.1822C>T p.L608= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1242530200, COSV56493437; called by muse, varscan2
- MAGEB1 | c.597G>T p.G199= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100975139; called by muse, mutect2
- MATK | c.828G>A p.E276= (on ENST00000310132 / NM_139355.3; = p.E277= on NM_002378.4) | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV59557104; called by muse, mutect2, varscan2
- NFKB2 | c.561G>C p.L187= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV51876090; called by muse, mutect2, varscan2
- OR6C1 | c.744C>T p.I248= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV101110487, COSV65574638; called by muse, mutect2, varscan2
- POLRMT | c.1905G>T p.A635= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV52119420, COSV99241754; called by muse, mutect2, varscan2
- PRSS16 | c.696C>A p.T232= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV57917213; called by muse, mutect2, varscan2
- RUSC1 | c.480C>T p.F160= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV52743305; called by muse, mutect2, varscan2
- USH2A | c.8349G>A p.L2783= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV56450207; called by muse, mutect2, varscan2
- CD99 | c.67+501T>G | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as COSV66990617; called by muse, mutect2, varscan2
- DDX41 | c.*585C>T | 3'UTR (SNP) | VAF 68/201 reads (34%) | catalogued as rs748765304, COSV57252649; called by muse, mutect2, varscan2
